Somatic mutation profile of tumor specimen TCGA-SI-A71P-01A (aliquot TCGA-SI-A71P-01A-12D-A33E-09) from TCGA case TCGA-SI-A71P, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of upper limb and shoulder; Age at diagnosis: 50.3 years (18,367 days).
Specimen TCGA-SI-A71P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9aec205-fc0e-49ae-ae04-cf948afd4653.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SI-A71P-10A (Blood Derived Normal), aliquot TCGA-SI-A71P-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8b3d9f9-91c4-41a4-9869-d945f98d0280

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 24, Silent 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL6 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100256543; called by muse, mutect2, varscan2
- CXXC1 | c.1451T>A p.I484N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99496835; called by muse, mutect2, varscan2
- DCAF5 | c.1552C>G p.R518G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV100432688, COSV58463376; called by muse, mutect2
- DOCK7 | c.2717G>A p.G906E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.269); catalogued as COSV99225387; called by muse, mutect2, varscan2
- DRC1 | c.45C>G p.D15E | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs751667577, COSV99985577; called by muse, mutect2
- FBXO41 | c.2584G>A p.G862S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753033564, COSV99721436; called by muse, mutect2, varscan2
- GRK3 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.71); catalogued as rs1314694248, COSV100151817; called by muse, mutect2
- KCTD8 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV100759874; called by muse, mutect2
- LONRF2 | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101111013; called by muse, mutect2, varscan2
- LRRN2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs1483947141; called by muse, varscan2
- MYH9 | c.4334A>C p.K1445T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99339418; called by muse, mutect2, varscan2
- NCOR1 | c.992G>A p.R331K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV99251203; called by muse, mutect2, varscan2
- NLRP12 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112159191, COSV100145574; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- PCARE | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.183); catalogued as COSV100527745; called by muse, mutect2, varscan2
- PRAMEF19 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1391863549; called by muse, mutect2, varscan2
- QKI | c.673G>C p.A225P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.548); catalogued as rs772401666, COSV51694223; called by muse, mutect2, varscan2
- SIN3A | c.2620C>G p.Q874E | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1395755178, COSV100845202; called by muse, mutect2, varscan2
- SLC22A8 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV100268002; called by muse, mutect2, varscan2
- ST18 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV99390510; called by mutect2, varscan2
- TASOR2 | c.2812T>C p.S938P | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as COSV100050762; called by muse, mutect2, varscan2
- TKT | c.406G>C p.A136P | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99964948, COSV99965108; called by muse, mutect2, varscan2
- ZBED9 | c.3283G>T p.D1095Y | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71729840; called by muse, mutect2, varscan2
- ZNF133 | c.811G>A p.V271M (on ENST00000316358 / NM_001352454.2; = p.V270M on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as COSV60367708; called by muse, mutect2, varscan2
- ZNF407 | c.3173G>A p.R1058H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs368385934; called by muse, mutect2, varscan2
- NF1 | c.1514dup p.L506Afs*5 | Frame Shift Ins (INS) | VAF 38/208 reads (18%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.4759C>T p.L1587= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99970147; called by mutect2, varscan2
- ATIC | c.798A>G p.K266= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99378031; called by muse, mutect2
- DUSP1 | c.999C>T p.T333= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1283076146, COSV99496010; called by muse, mutect2, varscan2
- IGHD | c.252C>T p.C84= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs745541015, COSV66655058; called by muse, mutect2, varscan2
- PTTG1IP | c.360C>T p.C120= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs1334646423, COSV100445935; called by muse, varscan2
- RYR3 | c.5194C>T p.L1732= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV101213388; called by muse, mutect2, varscan2
